Somatic mutation profile of tumor specimen TCGA-CF-A47Y-01A (aliquot TCGA-CF-A47Y-01A-11D-A23U-08) from TCGA case TCGA-CF-A47Y, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: Low Grade; Age at diagnosis: 55.9 years (20,432 days).
Specimen TCGA-CF-A47Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 07a6647b-c003-4f60-a54d-f1da21c9d609.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CF-A47Y-10A (Blood Derived Normal), aliquot TCGA-CF-A47Y-10A-01D-A23U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14e21029-e9cc-46be-a4eb-2b23db1f0f26

The open-access MAF lists 77 somatic variants for this specimen: 56 protein-altering or splice-affecting, 17 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 17, Nonsense Mutation 8, Intron 2, Splice Region 2, 3'UTR 1, Frame Shift Del 1, Splice Site 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EBF3 | c.86C>A p.S29* | Nonsense Mutation (SNP) | VAF 15/48 reads (31%) | catalogued as rs778076484, COSV100799225; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FGFR3 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 14/21 reads (67%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913482, CM950469, COSV53390662; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 17/47 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A2M | c.1227C>G p.I409M | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.515); catalogued as COSV59393193; called by muse, mutect2, varscan2
- AHR | c.2482C>T p.Q828* | Nonsense Mutation (SNP) | VAF 16/178 reads (9%) | catalogued as COSV99619740; called by muse, mutect2
- ASAH1 | c.418G>T p.D140Y | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV50505005; called by muse, mutect2, varscan2
- ATE1 | c.975G>A p.E325= | Splice Region (SNP) | VAF 25/58 reads (43%) | catalogued as COSV56444091; called by muse, mutect2, varscan2
- BDP1 | c.5134G>C p.G1712R | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV62435405; called by muse, mutect2, varscan2
- BRD2 | c.1003C>T p.Q335* | Nonsense Mutation (SNP) | VAF 14/140 reads (10%) | catalogued as COSV66374215; called by muse, mutect2
- C20orf194 | c.2993C>A p.S998Y | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.332); catalogued as COSV52704102; called by muse, mutect2, varscan2
- CCDC138 | c.165C>G p.I55M | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.206); catalogued as rs1280906610, COSV51709650; called by muse, mutect2, varscan2
- CCDC74A | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.932); catalogued as COSV54609435; called by muse, mutect2, varscan2
- CCDC88C | c.1058G>A p.R353K | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.63); PolyPhen benign (0.401); catalogued as rs368007696; called by muse, varscan2
- CNGB3 | c.207A>G p.I69M | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs35077504, COSV60699529; called by muse, mutect2, varscan2
- DZIP1 | c.1236_1237insG p.F413Vfs*3 | Frame Shift Ins (INS) | VAF 39/100 reads (39%) | catalogued as COSV61270774; called by mutect2, pindel, varscan2
- EFHD2 | c.217C>T p.Q73* | Nonsense Mutation (SNP) | VAF 14/40 reads (35%) | catalogued as rs771172023, COSV101044398; called by muse, mutect2, varscan2
- ENG | c.1616T>A p.V539E | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV61229264; called by muse, mutect2, varscan2
- F5 | c.6453G>C p.K2151N | Missense Mutation (SNP) | VAF 60/148 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV63126296, COSV63129143; called by muse, mutect2, varscan2
- FADD | c.447G>C p.K149N | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV57229736; called by muse, mutect2
- FRY | c.2372T>C p.L791P | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.905); catalogued as COSV66564377, COSV66581484; called by muse, mutect2, varscan2
- FSTL5 | c.1055G>C p.R352T | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as rs200663952, COSV60234216, COSV60234705; called by muse, mutect2, varscan2
- GFOD1 | c.1117C>T p.P373S | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.328); catalogued as COSV64955476; called by muse, mutect2, varscan2
- H2BC14 | c.282G>T p.E94D | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.211); catalogued as COSV60798756, COSV60798917; called by muse, mutect2, varscan2
- HERC2 | c.7577A>T p.E2526V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.249); catalogued as COSV99874023; called by muse, mutect2, varscan2
- HNRNPK | c.1008+2T>G p.X336_splice | Splice Site (SNP) | VAF 64/150 reads (43%) | catalogued as COSV61091250; called by muse, mutect2, varscan2
- JAG1 | c.2162A>G p.Y721C | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV54763638; called by muse, mutect2, varscan2
- KDM6A | c.3182C>G p.S1061* | Nonsense Mutation (SNP) | VAF 16/20 reads (80%) | catalogued as COSV65037520; called by muse, mutect2, varscan2
- KIDINS220 | c.2802C>G p.I934M | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.918); catalogued as COSV56760033; called by muse, mutect2, varscan2
- KMT2C | c.10201A>T p.K3401* | Nonsense Mutation (SNP) | VAF 78/198 reads (39%) | catalogued as COSV100072187; called by muse, mutect2, varscan2
- MGAT3 | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.007); catalogued as COSV57868972; called by muse, mutect2, varscan2
- MME | c.210C>G p.I70M | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV64711348; called by muse, mutect2, varscan2
- MPEG1 | c.339C>G p.Y113* | Nonsense Mutation (SNP) | VAF 61/153 reads (40%) | catalogued as COSV99915463; called by muse, mutect2, varscan2
- MPV17L2 | c.414G>T p.E138D | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.78); PolyPhen benign (0.006); catalogued as COSV55854080; called by muse, mutect2, varscan2
- NTRK2 | c.2192C>T p.T731M (on ENST00000323115 / NM_001369534.1; = p.T747M on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/111 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52870633, COSV52876088; called by muse, mutect2, varscan2
- OR11A1 | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV65821306, COSV65821408; called by muse, mutect2, varscan2
- PCDHGB2 | c.1676C>T p.A559V | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.604); catalogued as COSV54017424; called by muse, mutect2, varscan2
- PDHA2 | c.578G>A p.G193E | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54782458; called by muse, mutect2, varscan2
- PLCB1 | c.2500G>A p.D834N | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV62071110; called by muse, mutect2, varscan2
- PLXNA2 | c.1652G>A p.R551Q | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.983); catalogued as rs768278879, COSV65445602; called by muse, mutect2, varscan2
- PRPSAP2 | c.724G>C p.E242Q | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.206); catalogued as COSV52068239; called by muse, mutect2, varscan2
- PRUNE2 | c.3541G>T p.E1181* | Nonsense Mutation (SNP) | VAF 32/92 reads (35%) | catalogued as COSV100944598; called by muse, mutect2, varscan2
- PSG2 | c.497T>A p.I166N | Missense Mutation (SNP) | VAF 115/285 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.043); catalogued as COSV61546754; called by muse, mutect2, varscan2
- RNF112 | c.1451C>G p.S484C | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs774093121, COSV71327132; called by muse, mutect2, varscan2
- RPL28 | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.14); catalogued as rs1378497617, COSV59805965; called by muse, mutect2
- SEC14L2 | c.1179G>T p.K393N | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.239); catalogued as COSV56742459; called by muse, mutect2, varscan2
- SF3B3 | c.916G>C p.E306Q | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV56791435; called by muse, mutect2, varscan2
- SPTLC2 | c.480C>T p.F160= | Splice Region (SNP) | VAF 26/65 reads (40%) | catalogued as COSV53643582; called by muse, mutect2, varscan2
- TENM1 | c.5782C>T p.L1928F | Missense Mutation (SNP) | VAF 44/48 reads (92%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.949); catalogued as COSV64445577; called by muse, mutect2, varscan2
- TENM1 | c.654G>T p.R218S | Missense Mutation (SNP) | VAF 58/70 reads (83%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); catalogued as COSV64445586; called by muse, mutect2, varscan2
- TLR9 | c.2025C>A p.F675L | Missense Mutation (SNP) | VAF 47/99 reads (47%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV62348700; called by muse, mutect2, varscan2
- TMEM243 | c.187T>C p.F63L | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.973); catalogued as COSV57539462; called by muse, mutect2, varscan2
- TTC3 | c.4378C>T p.H1460Y | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.47); PolyPhen benign (0.04); catalogued as COSV61297016; called by muse, mutect2, varscan2
- WRN | c.1307A>G p.Y436C | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1290717956, COSV53308380; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF595 | c.1088C>G p.S363C | Missense Mutation (SNP) | VAF 56/68 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV59554326; called by muse, mutect2, varscan2
- CNR1 | c.134del p.P45Hfs*6 | Frame Shift Del (DEL) | VAF 35/78 reads (45%) | called by mutect2, pindel, varscan2
- TRDV3 | c.265C>G p.L89V | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- BNIP1 | c.300C>G p.L100= | Silent (SNP) | VAF 32/83 reads (39%) | catalogued as COSV51572218; called by muse, varscan2
- BNIP1 | c.360C>G p.L120= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as rs1433122612, COSV51572239; called by muse, varscan2
- KIF1B | c.1632T>A p.S544= (on ENST00000377086 / NM_001365952.1; = p.S498= on NM_015074.3) | Silent (SNP) | VAF 28/55 reads (51%) | catalogued as COSV55817207; called by muse, mutect2, varscan2
- MAN2B2 | c.462C>T p.G154= | Silent (SNP) | VAF 3/46 reads (7%) | catalogued as COSV99577461; called by muse, mutect2
- MAPK4 | c.411C>G p.L137= | Silent (SNP) | VAF 29/67 reads (43%) | catalogued as rs750761382, COSV68544144; called by muse, mutect2, varscan2
- MARCHF6 | c.1326G>C p.L442= | Silent (SNP) | VAF 6/81 reads (7%) | catalogued as COSV56887740; called by muse, mutect2
- MUC2 | c.1788C>T p.V596= | Silent (SNP) | VAF 5/9 reads (56%) | called by muse, mutect2, varscan2
- MYOZ3 | c.684C>G p.L228= | Silent (SNP) | VAF 11/133 reads (8%) | catalogued as COSV51741241; called by muse, mutect2
- PCDHB6 | c.474T>C p.D158= | Silent (SNP) | VAF 79/203 reads (39%) | catalogued as COSV50739238, COSV99170493; called by muse, mutect2, varscan2
- PRR12 | c.2739C>T p.L913= (on ENST00000615927; = p.L1734= on NM_020719.3) | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as rs1568430279, COSV101330678; called by muse, mutect2
- SNX20 | c.327C>T p.N109= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as rs1259547843, COSV56059316; called by muse, mutect2, varscan2
- ST6GAL1 | c.732C>G p.L244= | Silent (SNP) | VAF 17/166 reads (10%) | catalogued as COSV51475819; called by muse, mutect2, varscan2
- TLR9 | c.2961C>G p.L987= | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as COSV62348692; called by muse, mutect2, varscan2
- TSHZ1 | c.2226C>T p.F742= (on ENST00000580243 / NM_001308210.2; = p.F697= on NM_005786.6) | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as COSV59018245; called by muse, mutect2, varscan2
- ZNF540 | c.726C>T p.P242= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as COSV57111762; called by muse, mutect2, varscan2
- ZNF552 | c.525G>T p.G175= | Silent (SNP) | VAF 45/117 reads (38%) | catalogued as COSV66971986; called by muse, mutect2, varscan2
- ZNF552 | c.264G>A p.K88= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV101197532; called by muse, mutect2, varscan2
- GNA12 | c.526-29142C>G | Intron (SNP) | VAF 5/19 reads (26%) | catalogued as COSV51746098; called by muse, varscan2
- PHACTR1 | c.251-119515G>C | Intron (SNP) | VAF 12/26 reads (46%) | catalogued as COSV60683914; called by muse, mutect2, varscan2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 11/34 reads (32%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2, varscan2
- XIRP2 | c.*1278del | 3'UTR (DEL) | VAF 13/50 reads (26%) | called by mutect2, pindel, varscan2
